CCDI case PBBVDR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/89db2021-b1c8-40cf-a7bb-d937b19c9b79

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sertoli cell tumor, NOS: ICD-O-3 morphology code: 8640/1; Tissue or organ of origin: Ovary; Age at diagnosis: 15.4 years (5,636 days).

Biospecimens (3 samples)
- Sample 0DIKJF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIKJM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIKK2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
